Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3YH, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3YH-06A (Metastatic).

[page 1 of 3]
**SurgPath Final
Temporary Copy**

Page 1 of 3

FINAL DIAGNOSIS

- A) Thyroid gland, total thyroidectomy: Multifocal papillary carcinoma involving the right and left sides of the thyroid (right > left) ranging in size < 0.1 – 4.5 cm in greatest dimension. The surgical margins are negative for tumor and definite extrathyroidal extension is not identified. Lymphovascular invasion is present. Multiple (10 of 14) perithyroidal lymph nodes are positive for metastatic papillary thyroid carcinoma. One right parathyroid gland is also identified. See synoptic findings below.
- B) Left paratracheal lymph nodes, excision: One lymph node is negative for tumor. Benign thymic tissue is also identified.
- C) Right neck contents, dissection: Multiple (3 of 25) lymph nodes are involved by metastatic papillary thyroid carcinoma.

A: Thyroid Gland

HISTOLOGIC TYPE:

Papillary carcinoma
Classical (usual)

ICD-O3

carcinoma, papillary, thyroid
8260/3

TUMOR FOCALITY:

Multifocal (specify):
Bilateral

Site: lymph node, NOS
C77.9

TUMOR SIZE:

Greatest Dimension: 4.5 cm

8-3-12 RD

PRIMARY TUMOR (pT):

pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

REGIONAL LYMPH NODES (pN):

pN1b: Metastases to unilateral, bilateral or contralateral cervical (Levels I, II, III, IV, V) or retropharyngeal or superior mediastinal lymph nodes (Level VII).

NUMBER OF LYMPH NODE(S) INVOLVED: 13

NUMBER OF LYMPH NODE(S) EXAMINED: 40

[page 2 of 3]
DISTANT METASTASIS (pM):

Not applicable

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Present:

EXTRATHYROIDAL EXTENSION:

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Parathyroid gland(s):

Within normal limits

SPECIMEN RECEIVED

- A) THYROID GLAND AND NODES, FS
- B) LEFT PARATRACHEAL LYMPH NODE
- C) RIGHT NECK CONTENTS

FROZEN SECTION

- A) Thyroid gland, total thyroidectomy: Papillary thyroid carcinoma forming a predominant nodule in the right lobe. A representative perithyroidal lymph node is also positive for metastatic papillary carcinoma.

GROSS DESCRIPTION

A) Received fresh for frozen section labeled "thyroid gland and nodes" is a complete thyroidectomy specimen with attached soft tissues weighing 65 grams, and measuring 10.0 x 7.0 x 2.5 cm overall. The specimen is inked with black ink, serially sectioned, and reveals a large yellow/tan to tan/pink indurated mass in the right lobe of the thyroid measuring 4.5 cm in greatest dimension. Touch preps are made, and a representative section of that mass is submitted for frozen section as A1. Additional small nodular areas are identified within the thyroid. Multiple enlarged indurated cystic lymph nodes are identified in the attached fatty soft tissues measuring up to 2.0 cm in greatest dimension. A portion of the largest lymph node

[page 3 of 3]
is submitted for frozen section as A2. A portion of the thyroid mass and a portion of the indurated lymph node are submitted for the thyroid research study. Additional sections are submitted for permanent section as follows: A3-A6 additional sections of large mass within right lobe, A7 bisected second discrete nodule within right lobe, A8 bisected third discrete nodule within right lobe, A9 fourth smaller nodule in right lobe, A10 isthmus, A11-A12 nodules in left lobe, A13 representative section of uninvolved left lobe, A14 representative section of uninvolved right lobe, A15 additional section of large cystic tumor replaced lymph node, A16 representative sections of second tumor replaced lymph node, A17 representative sections of third tumor replaced lymph node, A18 bisected lymph node, A19 bisected lymph node, A20 bisected lymph node, A21 additional smaller lymph nodes.

B) Received in formalin labeled "left paratracheal lymph node" are two irregular portions of pink/tan to yellow/tan soft tissue measuring 0.7 cm and 2.5 cm in greatest dimension, respectively. The larger portion is bisected and submitted in B1 and B2, while the smaller portion is submitted in B3.

C) Received in formalin labeled "right neck contents" is an unoriented irregular portion of yellow lobulated soft tissue measuring 15.0 x 12.0 x 3.5 cm overall. A large cystic mass is identified measuring 4.5 cm in greatest dimension. On transection, this mass exudes brown/tan fluid and holds brown/tan material. Two additional large cystic masses are also identified measuring 3.5 cm and 2.5 cm in greatest dimension, respectively. Multiple additional lymph nodes measuring up to 1.7 cm in greatest dimension are also identified. Attached to the specimen is a portion of beefy red/tan skeletal muscle measuring 3.0 cm in greatest dimension. The muscle appears unremarkable. Representative sections are submitted for permanent section as follows: C1-C2 sections through largest cystic mass, C3-C4 sections through second cystic mass, C5 representative sections of third cystic mass, C6 bisected lymph nodes, C7 bisected lymph node, C8-C11 additional possible lymph nodes, C12 skeletal muscle.

CLINICAL INFORMATION
THYROID CANCER

Diagnostic Discrepancy		☒

Source: NCI Genomic Data Commons file dfe5be03-2716-4414-8360-871e1c9cd050 (TCGA-J8-A3YH.06491CF9-5C17-43B7-A214-2B039508412B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).